Gene-level copy-number profile of tumor specimen TCGA-13-1817-02A from TCGA case TCGA-13-1817, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,771 days).
Specimen TCGA-13-1817-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.25af523c-c59e-478e-ae23-bd07cf9944f4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1817-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 361 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/0769489c-9dab-41a8-9b27-3d8b0f0062e9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 533; copy number 1: 1; copy number 2: 25,389; copy number 3: 1,079; copy number 4: 26,793; copy number 5: 1,445; copy number 6: 4,417; copy number 7: 86; copy number 8: 296; copy number 9: 198; copy number 13: 25.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 1 gene (within-gene range 0–2): AC109583.1.
- chr3:46,719,583–46,834,095, 7 genes (within-gene range 0–2): PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P, PRSS42P.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–3): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr12:15,151,923–15,155,283, 1 gene: RERG-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 223 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,391,313–244,731,586, 198 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 13 (within-gene range 4–13): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 13: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
